Somatic mutation profile of tumor specimen BA2655D (aliquot aq-BA2655D) from BEATAML1.0 case 2458, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.8 years (21,487 days).
Specimen BA2655D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cb3a891-0710-4e4e-be0d-7b1d1dcce4f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2626D (Solid Tissue Normal), aliquot aq-BA2626D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4e83298-5c55-44c5-804e-dcd83761c24c

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- DACT1 | c.462C>G p.D154E | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761489904; called by muse, mutect2
- GPHB5 | c.261C>A p.N87K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs376425106; called by muse, mutect2, varscan2
- SFTPB | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as rs758367650; called by muse, varscan2
- VRK1 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99388664; called by muse, mutect2
- WFS1 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs150394063, COSV56987206; called by muse, mutect2, varscan2
- DHX33 | c.1919C>G p.T640S | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPACA4 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM240C | c.60C>T p.Y20= | Silent (SNP) | VAF 31/241 reads (13%) | catalogued as rs780265692; called by muse, mutect2, varscan2
- SETX | c.160T>C p.L54= | Silent (SNP) | VAF 22/276 reads (8%) | catalogued as rs1368647249; called by muse, mutect2
- CASP8 | c.1-8195G>C | Intron (SNP) | VAF 30/403 reads (7%) | called by muse, mutect2
